Somatic mutation profile of tumor specimen C3L-01663-02 (aliquot CPT0091610009) from CPTAC case C3L-01663, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 73.6 years (26,868 days).
Specimen C3L-01663-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d4b4037-c211-4f52-81b5-715bfd1d86a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01663-31 (Blood Derived Normal), aliquot CPT0093630002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cadc381c-da64-4faa-b23c-d15bf77b7c24

The open-access MAF lists 449 somatic variants for this specimen: 320 protein-altering or splice-affecting, 76 silent, 53 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 283, Silent 76, Intron 27, Nonsense Mutation 15, 3'UTR 9, RNA 8, Splice Site 7, 5'UTR 6, Frame Shift Del 6, Splice Region 4, Frame Shift Ins 4, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 22/189 reads (12%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 22/257 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 153/556 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACACB | c.5635C>T p.H1879Y | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.112); catalogued as rs369208008; called by muse, mutect2
- ALG10B | c.1120G>C p.V374L | Missense Mutation (SNP) | VAF 19/245 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.251); catalogued as COSV58142409; called by muse, mutect2
- ASH1L | c.8179G>A p.E2727K (on ENST00000368346 / NM_001366177.2; = p.E2722K on NM_018489.3) | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV64205883; called by muse, mutect2
- ATP2A1 | c.2254G>A p.A752T | Missense Mutation (SNP) | VAF 81/397 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as rs201798363, COSV62870624; called by muse, mutect2, varscan2
- BCORL1 | c.2079C>G p.I693M | Missense Mutation (SNP) | VAF 69/355 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.104); catalogued as COSV54392346; called by muse, mutect2, varscan2
- BRINP3 | c.1365C>A p.D455E | Missense Mutation (SNP) | VAF 46/231 reads (20%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.577); catalogued as COSV66520136; called by muse, mutect2, varscan2
- C1QTNF4 | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV56783437; called by muse, mutect2, varscan2
- CLNS1A | c.115A>G p.I39V | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99627962; called by muse, mutect2, varscan2
- CNTNAP5 | c.251A>G p.N84S | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.081); catalogued as COSV70477518, COSV70498035; called by muse, mutect2
- COL20A1 | c.643A>G p.K215E | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as rs1317941212; called by muse, mutect2, varscan2
- CPED1 | c.1303G>T p.G435C | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as rs200333617; called by muse, mutect2, varscan2
- CYP4Z1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs1206792114, COSV61964908; called by muse, mutect2, varscan2
- DCHS1 | c.8699T>A p.L2900Q | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54997038; called by muse, mutect2
- DMD | c.7450G>A p.D2484N | Missense Mutation (SNP) | VAF 44/400 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as rs773102625, COSV58906850; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.9287G>A p.R3096Q | Missense Mutation (SNP) | VAF 327/643 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs1388732051, COSV54203252; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNMT1 | c.3713G>A p.R1238H | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780156714; called by muse, mutect2, varscan2
- DOCK3 | c.2516G>T p.R839M | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV99814136; called by muse, mutect2
- DPYS | c.1077A>G p.I359M | Missense Mutation (SNP) | VAF 17/542 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as rs1221647712; called by muse, mutect2
- EEPD1 | c.1334T>C p.I445T | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV54197314; called by muse, mutect2
- EGFR | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 44/404 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.888); catalogued as COSV51803429, COSV51845825; called by muse, mutect2, varscan2
- ERICH3 | c.3625C>T p.R1209C | Missense Mutation (SNP) | VAF 54/244 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.258); catalogued as COSV100444744, COSV58616267; called by muse, mutect2, varscan2
- ERMARD | c.1661C>T p.S554L | Missense Mutation (SNP) | VAF 38/392 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs759294481; called by muse, mutect2
- FANCM | c.973G>T p.D325Y | Missense Mutation (SNP) | VAF 23/290 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV57501881; called by muse, mutect2
- FNBP1L | c.630G>T p.Q210H | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.991); catalogued as rs1283015959; called by muse, mutect2
- GABRA3 | c.377G>T p.R126I | Missense Mutation (SNP) | VAF 66/450 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64795768; called by muse, mutect2, varscan2
- GCM2 | c.447C>G p.I149M | Missense Mutation (SNP) | VAF 24/495 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65275687; called by muse, mutect2
- GCN1 | c.1091C>G p.S364* | Nonsense Mutation (SNP) | VAF 13/206 reads (6%) | catalogued as rs772153885, COSV100325406, COSV56105676; called by muse, mutect2
- GDF2 | c.974G>A p.S325N | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781792145; called by muse, mutect2, varscan2
- GIT2 | c.1366G>T p.D456Y | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV58084008; called by muse, mutect2, varscan2
- GMPPA | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV58007713; called by muse, mutect2, varscan2
- GRIK3 | c.982G>T p.D328Y | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66139066; called by muse, mutect2, varscan2
- HERC2 | c.3520C>G p.L1174V | Missense Mutation (SNP) | VAF 31/432 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV55350517; called by muse, mutect2
- HOXD12 | c.254T>C p.L85P | Missense Mutation (SNP) | VAF 48/317 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.966); catalogued as rs763537852; called by muse, mutect2, varscan2
- IGF1R | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 66/430 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs374465368; called by muse, mutect2, varscan2
- IGSF9B | c.2815G>T p.G939C | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.322); catalogued as rs771896150; called by muse, mutect2, varscan2
- IMPG1 | c.1355T>C p.M452T | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756901997; called by muse, mutect2, varscan2
- ITPRID1 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.088); catalogued as rs750792790, COSV60074268; called by muse, mutect2, varscan2
- KMT2D | c.9305del p.P3102Lfs*17 | Frame Shift Del (DEL) | VAF 33/225 reads (15%) | catalogued as COSV99040252, COSV99983483; called by mutect2, pindel, varscan2
- KRBA1 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as rs768503813; called by muse, mutect2
- MAP3K15 | c.2731G>A p.V911M | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as COSV100134709; called by muse, mutect2
- MCCC1 | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 22/504 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV55608726; called by muse, mutect2
- MRAS | c.248G>T p.R83L | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV56673673, COSV56673724; called by muse, mutect2
- MS4A14 | c.184A>G p.I62V | Missense Mutation (SNP) | VAF 52/255 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.207); catalogued as rs1358684242; called by muse, mutect2, varscan2
- MUC16 | c.21617C>G p.S7206C | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.79); catalogued as COSV67444771; called by muse, mutect2, varscan2
- MUC3A | c.839C>A p.T280K | Missense Mutation (SNP) | VAF 79/377 reads (21%) | SIFT deleterious, low confidence (0); catalogued as rs766031250; called by muse, mutect2, varscan2
- MYH15 | c.2722G>A p.E908K | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.437); catalogued as COSV99071909; called by muse, mutect2
- MYO16 | c.3912del p.N1305Tfs*4 | Frame Shift Del (DEL) | VAF 63/292 reads (22%) | catalogued as COSV62751323; called by mutect2, pindel, varscan2
- MYO18B | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.005); catalogued as rs1002665198; called by muse, mutect2
- NCAPD2 | c.545G>T p.R182L | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.743); catalogued as COSV59700573; called by muse, mutect2, varscan2
- NEB | c.8038C>G p.R2680G | Missense Mutation (SNP) | VAF 67/315 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV50807176; called by muse, mutect2, varscan2
- NFE2L2 | c.70T>G p.W24G | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67960091, COSV67960815, COSV67963035; called by muse, mutect2, varscan2
- NKX3-1 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV66513068; called by muse, mutect2
- NSD1 | c.6280G>C p.E2094Q | Missense Mutation (SNP) | VAF 51/412 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs549921292, CM074950, COSV61786753; called by muse, mutect2, varscan2
- OOSP1 | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.357); catalogued as rs146142782; called by muse, mutect2
- OR2T4 | c.577C>A p.P193T | Missense Mutation (SNP) | VAF 66/404 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.362); catalogued as COSV63545308; called by muse, mutect2, varscan2
- OR2T4 | c.578C>A p.P193H | Missense Mutation (SNP) | VAF 67/402 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63544276; called by muse, mutect2, varscan2
- OR52I1 | c.676C>T p.L226F | Missense Mutation (SNP) | VAF 14/297 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1178664382, COSV104395272; called by muse, mutect2
- OR5L2 | c.710C>G p.A237G | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV65724577; called by muse, mutect2, varscan2
- PALB2 | c.1308G>C p.K436N | Missense Mutation (SNP) | VAF 25/374 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV55169650; called by muse, mutect2
- PCDHA2 | c.689T>C p.I230T | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs1057279342; called by muse, mutect2
- PITPNM2 | c.1988G>A p.R663H | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs200737841; called by muse, mutect2, varscan2
- PPARGC1A | c.1978G>C p.E660Q | Missense Mutation (SNP) | VAF 10/257 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.153); catalogued as COSV53525151; called by muse, mutect2
- PPP1R3F | c.1628G>T p.R543L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99279120; called by muse, varscan2
- R3HDM1 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 44/363 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs747738172, COSV51525391; called by muse, varscan2
- RIC3 | c.500G>C p.R167T | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV58300284; called by muse, mutect2
- RIF1 | c.1906G>A p.A636T | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.288); catalogued as rs201470069; called by muse, mutect2, varscan2
- RIMS1 | c.189G>C p.K63N | Missense Mutation (SNP) | VAF 53/261 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV53454216, COSV53474170; called by muse, mutect2, varscan2
- RNF17 | c.2158G>A p.E720K | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.034); catalogued as COSV55033492; called by muse, mutect2
- RPL5 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 26/342 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as rs764283613; called by muse, mutect2
- SI | c.5250C>A p.T1750= | Splice Region (SNP) | VAF 72/370 reads (19%) | catalogued as COSV52296498; called by muse, mutect2, varscan2
- SORL1 | c.3593C>T p.T1198I | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1454415758; called by muse, mutect2, varscan2
- SPECC1L | c.2080G>C p.E694Q | Missense Mutation (SNP) | VAF 24/416 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58661739; called by muse, mutect2
- SPTLC2 | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 33/282 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV53640279, COSV53644293; called by muse, mutect2, varscan2
- STAG2 | c.2928T>A p.D976E | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.109); catalogued as rs1254278387, COSV54369194; called by muse, mutect2
- SUPT5H | c.2759G>T p.G920V | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as COSV63240241; called by muse, mutect2, varscan2
- TBC1D24 | c.1046A>G p.E349G (on ENST00000646147 / NM_001199107.2; = p.E343G on NM_020705.3) | Missense Mutation (SNP) | VAF 81/368 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as rs772317879; called by muse, mutect2, varscan2
- TFIP11 | c.716C>G p.S239C | Missense Mutation (SNP) | VAF 15/332 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.498); catalogued as COSV101316473; called by muse, mutect2
- THSD7A | c.958C>A p.Q320K | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV70260927; called by muse, mutect2, varscan2
- TMEM132D | c.2253C>G p.F751L | Missense Mutation (SNP) | VAF 20/392 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as COSV67162274; called by muse, mutect2
- TNN | c.2222G>T p.R741L | Missense Mutation (SNP) | VAF 140/479 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as rs537008413, COSV53433068; called by muse, mutect2, varscan2
- TNNT2 | c.717G>T p.L239= (on ENST00000236918; = p.L236= on NM_000364.4) | Splice Region (SNP) | VAF 60/372 reads (16%) | catalogued as COSV52664281; called by muse, mutect2, varscan2
- TSC2 | c.4211A>C p.K1404T | Missense Mutation (SNP) | VAF 66/296 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.107); catalogued as COSV51910343; called by muse, mutect2, varscan2
- TXNDC16 | c.243+2T>C p.X81_splice | Splice Site (SNP) | VAF 16/123 reads (13%) | catalogued as rs1229488564; called by muse, mutect2, varscan2
- UNC13C | c.3692G>A p.G1231D | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52856892; called by muse, mutect2, varscan2
- USHBP1 | c.436C>A p.P146T | Missense Mutation (SNP) | VAF 26/275 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as rs1339742945; called by muse, mutect2
- WDR87 | c.7666C>T p.L2556F | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.097); catalogued as COSV58208105; called by muse, mutect2, varscan2
- XIAP | c.71T>C p.V24A | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63023858; called by muse, mutect2
- ZBTB6 | c.1063C>T p.Q355* | Nonsense Mutation (SNP) | VAF 26/172 reads (15%) | catalogued as COSV65409260; called by muse, mutect2, varscan2
- ZNF275 | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs782081441, COSV100936467; called by muse, mutect2, varscan2
- ZNF287 | c.2103G>C p.E701D | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1244442596; called by muse, mutect2
- ZNF300 | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1177573064; called by muse, mutect2
- ZNF385D | c.923A>T p.N308I | Missense Mutation (SNP) | VAF 23/258 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV55745897; called by muse, mutect2
- ZNF446 | c.476C>G p.S159C | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); catalogued as COSV99543286; called by muse, mutect2
- ZNF536 | c.1922G>T p.R641L | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs756128270, COSV62826032; called by muse, mutect2
- ABCA1 | c.224G>T p.C75F | Missense Mutation (SNP) | VAF 27/410 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABHD17A | c.550dup p.I184Nfs*53 (on ENST00000292577 / NM_001130111.2; = p.I235Nfs*53 on NM_031213.4) | Frame Shift Ins (INS) | VAF 31/157 reads (20%) | called by mutect2, pindel, varscan2
- ACOT9 | c.993T>C p.G331= | Splice Region (SNP) | VAF 15/152 reads (10%) | called by muse, mutect2
- ADGB | c.2655A>T p.L885F | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.212); called by muse, mutect2
- AGO3 | c.1544G>T p.G515V | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- AHDC1 | c.4111G>T p.G1371C | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- AJUBA | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AK9 | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 13/206 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.163); called by muse, mutect2
- AKAP4 | c.1951G>C p.G651R | Missense Mutation (SNP) | VAF 30/295 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.763); called by muse, mutect2
- ALPK2 | c.2525T>A p.L842Q | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- AMER1 | c.2106G>C p.E702D | Missense Mutation (SNP) | VAF 21/532 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.311); called by muse, mutect2
- AMOT | c.2578C>T p.R860* (on ENST00000371959 / NM_001113490.1; = p.R451* on NM_133265.3) | Nonsense Mutation (SNP) | VAF 93/299 reads (31%) | called by muse, mutect2, varscan2
- ANKDD1A | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 7/205 reads (3%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.993); called by muse, mutect2
- ARAF | c.1699A>G p.I567V | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- ARHGAP11A | c.1128A>T p.E376D | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGAP29 | c.2229G>T p.L743F | Missense Mutation (SNP) | VAF 75/267 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGEF9 | c.1334C>G p.A445G | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- ARHGEF9 | c.811G>T p.A271S | Missense Mutation (SNP) | VAF 58/326 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ATAD5 | c.1106C>G p.S369C | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ATAD5 | c.4655C>A p.S1552Y | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ATG4B | c.797T>A p.F266Y | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- AUTS2 | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.733); called by muse, mutect2
- AXIN1 | c.1402G>C p.E468Q | Missense Mutation (SNP) | VAF 48/468 reads (10%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BAHCC1 | c.2294T>A p.L765Q | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BBX | c.1259G>T p.S420I | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- BCKDHB | c.906T>G p.I302M | Missense Mutation (SNP) | VAF 81/325 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BSX | c.428T>G p.L143R | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- BTNL9 | c.636A>T p.E212D | Missense Mutation (SNP) | VAF 15/340 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.334); called by muse, mutect2
- CABP7 | c.196G>C p.G66R | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA1H | c.1255G>A p.A419T | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- CADM1 | c.333G>T p.L111F | Missense Mutation (SNP) | VAF 77/442 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CASS4 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2
- CATSPERG | c.3278T>G p.L1093R | Missense Mutation (SNP) | VAF 57/342 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- CCDC40 | c.1975G>C p.E659Q | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.042); called by muse, mutect2
- CCDC8 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- CCT5 | c.1306G>T p.E436* | Nonsense Mutation (SNP) | VAF 30/781 reads (4%) | called by muse, mutect2
- CD96 | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 23/354 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CDC27 | c.2338G>C p.D780H | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2
- CDC34 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- CDK10 | c.33C>G p.I11M | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- CDRT1 | c.1797G>A p.W599* | Nonsense Mutation (SNP) | VAF 11/310 reads (4%) | called by muse, mutect2
- CEMP1 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.859); called by muse, mutect2
- CEP295 | c.4743G>C p.E1581D | Missense Mutation (SNP) | VAF 14/269 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.584); called by muse, mutect2
- CFAP47 | c.4162T>A p.S1388T | Missense Mutation (SNP) | VAF 23/262 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.345); called by muse, mutect2
- CFAP57 | c.113G>C p.C38S | Missense Mutation (SNP) | VAF 95/399 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- CHAMP1 | c.2019G>T p.M673I | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHM | c.1217G>T p.C406F | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHODL | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- CHTOP | c.384G>T p.R128S | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CNKSR2 | c.810+1G>C p.X270_splice | Splice Site (SNP) | VAF 14/117 reads (12%) | called by muse, mutect2, varscan2
- COL11A1 | c.4640C>G p.P1547R | Missense Mutation (SNP) | VAF 38/314 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL11A1 | c.1490T>C p.F497S | Missense Mutation (SNP) | VAF 52/387 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- COPS2 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- CPS1 | c.319C>G p.P107A | Missense Mutation (SNP) | VAF 14/425 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CRYBG2 | c.1405G>C p.A469P | Missense Mutation (SNP) | VAF 14/257 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); called by muse, mutect2
- CYP20A1 | c.1239-2A>T p.X413_splice | Splice Site (SNP) | VAF 9/150 reads (6%) | called by muse, mutect2
- DCLK2 | c.168C>G p.F56L | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- DLK2 | c.466C>G p.L156V | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DMD | c.11009C>A p.S3670* | Nonsense Mutation (SNP) | VAF 32/362 reads (9%) | called by muse, mutect2
- DNAH9 | c.12171C>G p.F4057L | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DOCK7 | c.2692A>G p.S898G | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- DPYD | c.1606G>C p.E536Q | Missense Mutation (SNP) | VAF 13/430 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2
- DTX3L | c.1092dup p.P365Tfs*15 | Frame Shift Ins (INS) | VAF 53/345 reads (15%) | called by mutect2, pindel, varscan2
- EFCAB1 | c.413C>G p.S138C | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- EFR3A | c.1609G>T p.G537C | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- ENPP3 | c.1287C>G p.C429W | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EXD1 | c.545A>T p.Q182L | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FAM160A1 | c.1817G>T p.G606V | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- FAM171A1 | c.115C>T p.H39Y | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- FAM47B | c.1354G>T p.D452Y | Missense Mutation (SNP) | VAF 38/424 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- FAM98A | c.553A>G p.N185D | Missense Mutation (SNP) | VAF 10/253 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.116); called by muse, mutect2
- FBXO40 | c.838A>T p.T280S | Missense Mutation (SNP) | VAF 26/290 reads (9%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2
- FGF12 | c.242A>T p.Q81L (on ENST00000454309 / NM_021032.5; = p.Q19L on NM_004113.6) | Missense Mutation (SNP) | VAF 85/264 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- FLG2 | c.21T>A p.S7R | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- G6PC2 | c.176G>T p.W59L | Missense Mutation (SNP) | VAF 62/257 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- GALR1 | c.549C>A p.N183K | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- GDF10 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.022); called by muse, mutect2
- GLMN | c.1474-1G>C p.X492_splice | Splice Site (SNP) | VAF 14/204 reads (7%) | called by muse, mutect2
- GOLGA6D | c.2046G>C p.Q682H | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GOLGA8S | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 27/547 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.422); called by muse, mutect2
- GPRASP1 | c.1270G>C p.E424Q | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- GYG2 | c.844C>G p.L282V | Missense Mutation (SNP) | VAF 18/337 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- GYPC | c.322G>T p.A108S | Missense Mutation (SNP) | VAF 73/428 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- H4C9 | c.241A>G p.T81A | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- HDAC6 | c.652C>T p.Q218* | Nonsense Mutation (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
- HMCN2 | c.11547G>A p.V3849= | Splice Region (SNP) | VAF 12/54 reads (22%) | called by muse, varscan2
- HMOX1 | c.258G>T p.K86N | Missense Mutation (SNP) | VAF 44/403 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- IBTK | c.2450C>T p.S817F | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- ICE1 | c.3139G>T p.G1047* | Nonsense Mutation (SNP) | VAF 29/315 reads (9%) | called by muse, mutect2
- IKZF1 | c.755A>G p.D252G | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- INPPL1 | c.2357A>G p.Q786R | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- IQUB | c.242A>T p.E81V | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ITGAD | c.1550G>A p.W517* | Nonsense Mutation (SNP) | VAF 42/160 reads (26%) | called by muse, mutect2, varscan2
- ITPR2 | c.1646A>T p.Y549F | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- KANK1 | c.3206T>G p.V1069G | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- KCNJ3 | c.764T>A p.F255Y | Missense Mutation (SNP) | VAF 54/296 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- KIAA0100 | c.6022G>A p.V2008I | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KIRREL2 | c.1397T>A p.I466N | Missense Mutation (SNP) | VAF 45/328 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- KLC2 | c.1382G>C p.R461P | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- KLRG2 | c.1089G>T p.E363D | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- KRCC1 | c.647A>G p.N216S | Missense Mutation (SNP) | VAF 53/241 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KRT24 | c.1304A>T p.K435M | Missense Mutation (SNP) | VAF 91/368 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LCK | c.1394G>C p.C465S | Missense Mutation (SNP) | VAF 31/423 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- LGR5 | c.62G>C p.G21A | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LHX5 | c.1110C>A p.S370R | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- LIN54 | c.1001C>T p.S334L | Missense Mutation (SNP) | VAF 23/234 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.261); called by muse, mutect2
- LMTK2 | c.3254C>A p.T1085K | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.023); called by mutect2, varscan2
- LRP1B | c.8403del p.N2802Ifs*58 | Frame Shift Del (DEL) | VAF 13/90 reads (14%) | called by mutect2, pindel, varscan2
- LRRC9 | c.1994A>G p.K665R | Missense Mutation (SNP) | VAF 18/245 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.072); called by muse, mutect2
- MAB21L2 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEC2 | c.62A>T p.E21V | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- MAGEH1 | c.206C>G p.S69W | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- MAGEL2 | c.1180G>C p.V394L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated, low confidence (0.35); PolyPhen probably damaging (0.956); called by muse, mutect2
- MBD3 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 21/137 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.904); called by mutect2, varscan2
- MCRS1 | c.911-1G>C p.X304_splice | Splice Site (SNP) | VAF 10/215 reads (5%) | called by muse, mutect2
- MECOM | c.2548T>G p.F850V (on ENST00000468789 / NM_001105078.4; = p.F1038V on NM_004991.4) | Missense Mutation (SNP) | VAF 15/358 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MMRN2 | c.1372G>C p.E458Q | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- MRPS10 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 37/251 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MSH6 | c.2384T>G p.I795R | Missense Mutation (SNP) | VAF 43/387 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- MYH14 | c.1688C>A p.A563D | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYO10 | c.2073G>T p.R691S | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.033); called by muse, mutect2
- MYO1H | c.400A>T p.I134F | Missense Mutation (SNP) | VAF 13/192 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2
- MYO5A | c.5215G>T p.G1739W | Missense Mutation (SNP) | VAF 59/340 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MYT1 | c.1210G>T p.E404* | Nonsense Mutation (SNP) | VAF 24/162 reads (15%) | called by muse, mutect2, varscan2
- NALCN | c.4232C>T p.T1411I | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- NDUFS5 | c.9C>G p.F3L | Missense Mutation (SNP) | VAF 18/362 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.04); called by muse, mutect2
- NIPBL | c.869-1G>T p.X290_splice | Splice Site (SNP) | VAF 49/411 reads (12%) | called by muse, mutect2, varscan2
- NSMAF | c.2689C>A p.Q897K | Missense Mutation (SNP) | VAF 49/294 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- NUP62CL | c.216G>T p.M72I | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- OR4C11 | c.740T>C p.L247S | Missense Mutation (SNP) | VAF 85/180 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- OR5D16 | c.183G>T p.M61I | Missense Mutation (SNP) | VAF 8/216 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); called by muse, mutect2
- OR8K1 | c.172G>T p.D58Y | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- OSBP | c.1678G>T p.G560C | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OSBPL2 | c.551C>T p.A184V (on ENST00000313733 / NM_144498.4; = p.A172V on NM_014835.4) | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OTUD6A | c.376C>A p.R126S | Missense Mutation (SNP) | VAF 67/302 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- PCDH10 | c.1354C>A p.Q452K | Missense Mutation (SNP) | VAF 41/249 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PCDH11X | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 34/588 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDH17 | c.1201G>T p.G401W | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHGB3 | c.1805C>G p.A602G | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- PCNX1 | c.3845G>T p.S1282I | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PDCD11 | c.1240G>T p.G414W | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDHA1 | c.841C>A p.L281M | Missense Mutation (SNP) | VAF 35/399 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.946); called by muse, mutect2
- PDP2 | c.1403A>C p.Q468P | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- PENK | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 33/490 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2
- PODN | c.1408C>T p.H470Y (on ENST00000395871; = p.H422Y on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- POTEC | c.214T>G p.C72G | Missense Mutation (SNP) | VAF 85/561 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PPP4R3C | c.1222G>T p.V408L | Missense Mutation (SNP) | VAF 17/191 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2
- PRDM9 | c.1250C>A p.P417Q | Missense Mutation (SNP) | VAF 49/983 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.758); called by muse, mutect2
- PSD4 | c.2881C>G p.H961D | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2
- PUF60 | c.1453G>C p.E485Q (on ENST00000526683 / NM_001362896.2; = p.E468Q on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.846); called by muse, mutect2
- PWWP2A | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.815); called by muse, mutect2
- PXDN | c.2300T>A p.L767Q | Missense Mutation (SNP) | VAF 82/432 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- QSOX2 | c.265T>C p.S89P | Missense Mutation (SNP) | VAF 62/227 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- RAB40A | c.532C>A p.H178N | Missense Mutation (SNP) | VAF 28/420 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2
- RBMX | c.94G>A p.G32R | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RHBDF2 | c.1698C>G p.I566M | Missense Mutation (SNP) | VAF 19/330 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.321); called by muse, mutect2
- RNF222 | c.396C>A p.S132R | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- ROBO2 | c.3631G>C p.D1211H | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RPS8 | c.336G>A p.W112* | Nonsense Mutation (SNP) | VAF 15/218 reads (7%) | called by muse, mutect2
- RTKN2 | c.1210G>T p.E404* | Nonsense Mutation (SNP) | VAF 11/117 reads (9%) | called by muse, varscan2
- RYR1 | c.12224C>T p.A4075V | Missense Mutation (SNP) | VAF 93/307 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- RYR2 | c.11336A>T p.D3779V | Missense Mutation (SNP) | VAF 39/274 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- RYR3 | c.335G>T p.R112M | Missense Mutation (SNP) | VAF 34/238 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- SATB2 | c.1254G>A p.M418I | Missense Mutation (SNP) | VAF 18/526 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); called by muse, mutect2
- SAV1 | c.205A>T p.R69* | Nonsense Mutation (SNP) | VAF 25/211 reads (12%) | called by muse, mutect2, varscan2
- SCN2A | c.4189A>T p.R1397W | Missense Mutation (SNP) | VAF 59/278 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCX | c.295C>A p.R99S | Missense Mutation (SNP) | VAF 12/261 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SEMA6A | c.2191A>G p.K731E | Missense Mutation (SNP) | VAF 65/257 reads (25%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- SFSWAP | c.1623_1624del p.P542* | Frame Shift Del (DEL) | VAF 28/202 reads (14%) | called by pindel, varscan2
- SKOR2 | c.1340A>G p.K447R | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- SLC12A9 | c.318C>A p.F106L | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- SLC13A1 | c.116A>G p.Y39C | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLC22A10 | c.530G>A p.R177K | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.05); called by muse, mutect2
- SLC25A23 | c.1393dup p.V465Gfs*47 | Frame Shift Ins (INS) | VAF 42/274 reads (15%) | called by mutect2, pindel, varscan2
- SLC2A13 | c.91G>T p.D31Y | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.188); called by muse, mutect2
- SLC6A3 | c.128C>T p.T43I | Missense Mutation (SNP) | VAF 26/833 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.926); called by muse, mutect2
- SMIM21 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.001); called by muse, mutect2
- STAG1 | c.1744-1G>T p.X582_splice | Splice Site (SNP) | VAF 37/130 reads (28%) | called by muse, mutect2, varscan2
- STAU1 | c.317A>T p.N106I (on ENST00000371856 / NM_001319135.1; = p.N25I on NM_004602.3) | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- STYXL2 | c.2049C>A p.S683R | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SUSD1 | c.1199G>T p.S400I | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNE1 | c.9826G>A p.D3276N (on ENST00000367255 / NM_182961.4; = p.D3283N on NM_033071.3) | Missense Mutation (SNP) | VAF 20/325 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2
- SYT3 | c.1766C>A p.S589Y | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- TAAR6 | c.765A>T p.K255N | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TAF15 | c.524G>C p.R175T (on ENST00000605844 / NM_139215.3; = p.R172T on NM_003487.4) | Missense Mutation (SNP) | VAF 36/275 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- TAS2R5 | c.360G>C p.Q120H | Missense Mutation (SNP) | VAF 37/350 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- TDRD5 | c.1427T>C p.F476S | Missense Mutation (SNP) | VAF 20/369 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- TENM1 | c.4772G>T p.R1591L | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- TEX11 | c.2207G>C p.C736S (on ENST00000344304; = p.C721S on NM_031276.3) | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.527); called by muse, varscan2
- THSD7A | c.3259G>T p.V1087F | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2
- THSD7B | c.2785C>A p.Q929K | Missense Mutation (SNP) | VAF 33/230 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- TMED5 | c.425A>G p.Y142C | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); called by muse, mutect2
- TMEM132C | c.844C>A p.Q282K | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TNXB | c.8137G>T p.V2713L (on ENST00000647633; = p.V2466L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.905); called by muse, mutect2
- TPO | c.2615G>C p.R872T | Missense Mutation (SNP) | VAF 20/570 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2
- TPX2 | c.578G>A p.R193K | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM67 | c.1933G>T p.A645S | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.392); called by muse, varscan2
- TRO | c.1678C>A p.R560S | Missense Mutation (SNP) | VAF 16/195 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); called by muse, mutect2
- TRPM4 | c.2927G>T p.G976V | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TTN | c.13142del p.A4381Vfs*4 (on ENST00000591111; = p.A4335Vfs*4 on NM_003319.4) | Frame Shift Del (DEL) | VAF 16/96 reads (17%) | called by mutect2, pindel, varscan2
- TTN | c.1083G>T p.E361D | Missense Mutation (SNP) | VAF 19/402 reads (5%) | PolyPhen benign (0.006); called by muse, mutect2
- URB1 | c.2975dup p.M992Ifs*12 | Frame Shift Ins (INS) | VAF 13/86 reads (15%) | called by mutect2, pindel, varscan2
- USH2A | c.11246T>C p.L3749S | Missense Mutation (SNP) | VAF 37/329 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, varscan2
- VEPH1 | c.1745G>C p.R582T | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- WDFY4 | c.7532C>G p.S2511C | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2
- WDR49 | c.264_265del p.W89Gfs*28 (on ENST00000308378 / NM_001366158.1; = p.W430Gfs*28 on NM_001348951.2 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 39/295 reads (13%) | called by pindel, varscan2
- WEE2 | c.1664C>T p.S555F | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- XKR4 | c.877T>C p.W293R | Missense Mutation (SNP) | VAF 62/376 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XPNPEP2 | c.422T>A p.V141D | Missense Mutation (SNP) | VAF 76/334 reads (23%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- ZBTB22 | c.1845G>T p.W615C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZBTB45 | c.917C>A p.T306N | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBTB46 | c.118A>T p.K40* | Nonsense Mutation (SNP) | VAF 19/205 reads (9%) | called by muse, mutect2
- ZDBF2 | c.338C>A p.P113H | Missense Mutation (SNP) | VAF 53/332 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- ZIC5 | c.490C>A p.P164T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZMYM5 | c.1658A>T p.D553V | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF266 | c.1043G>T p.G348V | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ZNF280B | c.833A>G p.K278R | Missense Mutation (SNP) | VAF 20/416 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); called by muse, mutect2
- ZNF350 | c.1265G>C p.R422T | Missense Mutation (SNP) | VAF 10/266 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.32); called by muse, mutect2
- ZNF420 | c.1815T>G p.H605Q | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF598 | c.1685A>T p.Q562L | Missense Mutation (SNP) | VAF 62/283 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ZNF614 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 99/363 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF679 | c.179C>G p.S60C | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- ZNF718 | c.761C>G p.P254R | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2
- ALMS1 | c.4119A>G p.T1373= | Silent (SNP) | VAF 69/324 reads (21%) | called by muse, mutect2, varscan2
- ALOX5 | c.582C>T p.F194= | Silent (SNP) | VAF 14/209 reads (7%) | called by muse, mutect2
- ARFGEF2 | c.4836C>T p.F1612= | Silent (SNP) | VAF 36/668 reads (5%) | called by muse, mutect2
- ARMC3 | c.447T>C p.H149= | Silent (SNP) | VAF 32/152 reads (21%) | called by muse, mutect2, varscan2
- ASB3 | c.45A>T p.G15= | Silent (SNP) | VAF 62/316 reads (20%) | called by muse, mutect2, varscan2
- ATP10A | c.3108C>G p.V1036= | Silent (SNP) | VAF 10/226 reads (4%) | called by muse, mutect2
- BMX | c.372C>T p.F124= | Silent (SNP) | VAF 22/174 reads (13%) | catalogued as COSV100564501; called by muse, mutect2, varscan2
- CCNB3 | c.3933C>G p.A1311= | Silent (SNP) | VAF 15/116 reads (13%) | catalogued as rs782006480; called by muse, mutect2, varscan2
- CD33 | c.457C>T p.L153= | Silent (SNP) | VAF 50/156 reads (32%) | catalogued as COSV51805262; called by muse, mutect2, varscan2
- CFAP47 | c.9507C>T p.L3169= | Silent (SNP) | VAF 12/362 reads (3%) | called by muse, mutect2
- CNTN3 | c.330C>A p.V110= | Silent (SNP) | VAF 16/117 reads (14%) | called by muse, mutect2, varscan2
- CSNK1G3 | c.249A>G p.L83= | Silent (SNP) | VAF 62/214 reads (29%) | catalogued as rs894018748; called by muse, mutect2, varscan2
- DCAF8L2 | c.1017A>G p.E339= | Silent (SNP) | VAF 11/271 reads (4%) | called by muse, mutect2
- DKC1 | c.552C>G p.P184= | Silent (SNP) | VAF 74/421 reads (18%) | catalogued as COSV65777140; called by muse, mutect2, varscan2
- DOK6 | c.684G>T p.L228= | Silent (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- ERICH3 | c.2601T>A p.A867= | Silent (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- ESR1 | c.1344C>G p.L448= | Silent (SNP) | VAF 12/378 reads (3%) | catalogued as COSV52780820; called by muse, mutect2
- FAM47B | c.741C>A p.L247= | Silent (SNP) | VAF 26/266 reads (10%) | catalogued as COSV61453383; called by muse, mutect2
- FAT4 | c.12975A>C p.I4325= | Silent (SNP) | VAF 18/165 reads (11%) | called by muse, mutect2, varscan2
- FBN2 | c.1440A>T p.G480= | Silent (SNP) | VAF 34/216 reads (16%) | called by muse, mutect2, varscan2
- FGFBP1 | c.366A>T p.S122= | Silent (SNP) | VAF 26/189 reads (14%) | called by muse, mutect2, varscan2
- FOXC2 | c.492C>A p.R164= | Silent (SNP) | VAF 13/222 reads (6%) | called by muse, mutect2
- FSIP2 | c.14028T>C p.I4676= | Silent (SNP) | VAF 20/146 reads (14%) | called by muse, mutect2, varscan2
- FTSJ3 | c.2310A>C p.T770= | Silent (SNP) | VAF 23/285 reads (8%) | called by muse, mutect2
- GAD1 | c.192G>T p.V64= | Silent (SNP) | VAF 80/396 reads (20%) | called by muse, mutect2, varscan2
- GJA10 | c.294T>C p.Y98= | Silent (SNP) | VAF 28/242 reads (12%) | catalogued as rs769713121; called by muse, mutect2, varscan2
- GPRC5B | c.528C>T p.I176= | Silent (SNP) | VAF 23/213 reads (11%) | catalogued as rs761857600, COSV100314866; called by muse, mutect2, varscan2
- GSPT2 | c.1473C>G p.L491= | Silent (SNP) | VAF 16/345 reads (5%) | called by muse, mutect2
- IFNA17 | c.369G>C p.V123= | Silent (SNP) | VAF 25/385 reads (6%) | catalogued as COSV69738080; called by muse, mutect2
- KCNA1 | c.984G>T p.L328= | Silent (SNP) | VAF 34/276 reads (12%) | catalogued as rs565299396; called by muse, mutect2, varscan2
- KMT2D | c.8172C>T p.P2724= | Silent (SNP) | VAF 14/48 reads (29%) | called by muse, mutect2, varscan2
- LMTK2 | c.1497C>T p.S499= | Silent (SNP) | VAF 22/142 reads (15%) | catalogued as rs771357699; called by muse, mutect2, varscan2
- MFSD12 | c.1146C>T p.I382= | Silent (SNP) | VAF 17/126 reads (13%) | called by muse, mutect2, varscan2
- MS4A14 | c.1434T>C p.H478= | Silent (SNP) | VAF 73/335 reads (22%) | called by muse, mutect2, varscan2
- MUC5B | c.16017C>T p.R5339= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs374509500; called by muse, mutect2, varscan2
- MYH7 | c.4068G>A p.E1356= | Silent (SNP) | VAF 41/167 reads (25%) | called by muse, mutect2, varscan2
- NCBP1 | c.13C>A p.R5= | Silent (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- NPY5R | c.873G>A p.K291= | Silent (SNP) | VAF 8/198 reads (4%) | catalogued as COSV58450948; called by muse, mutect2
- NR5A2 | c.891T>C p.S297= (on ENST00000367362 / NM_205860.3; = p.S251= on NM_003822.5) | Silent (SNP) | VAF 89/471 reads (19%) | called by muse, mutect2, varscan2
- NYAP2 | c.696C>A p.G232= | Silent (SNP) | VAF 15/114 reads (13%) | called by muse, mutect2, varscan2
- OBSCN | c.948C>A p.L316= | Silent (SNP) | VAF 11/199 reads (6%) | called by muse, mutect2
- OCIAD2 | c.159G>A p.K53= | Silent (SNP) | VAF 8/134 reads (6%) | catalogued as COSV56716184; called by muse, mutect2
- OLFML1 | c.264G>A p.L88= | Silent (SNP) | VAF 101/330 reads (31%) | catalogued as rs772992576; called by muse, mutect2, varscan2
- OR10Q1 | c.426C>T p.R142= | Silent (SNP) | VAF 14/233 reads (6%) | catalogued as COSV57469838; called by muse, mutect2
- OR10S1 | c.777C>G p.L259= | Silent (SNP) | VAF 9/163 reads (6%) | called by muse, mutect2
- PCDH15 | c.1728G>A p.G576= | Silent (SNP) | VAF 90/317 reads (28%) | catalogued as COSV57263169; called by muse, mutect2, varscan2
- PCDHA6 | c.2106C>A p.I702= | Silent (SNP) | VAF 15/296 reads (5%) | catalogued as COSV65341853; called by muse, mutect2
- PKD1 | c.7725A>G p.P2575= | Silent (SNP) | VAF 105/592 reads (18%) | catalogued as rs1466412515; called by muse, mutect2, varscan2
- POLR3A | c.633G>C p.L211= | Silent (SNP) | VAF 113/426 reads (27%) | catalogued as COSV100965667; called by muse, mutect2, varscan2
- PRRT4 | c.1998C>T p.A666= | Silent (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- PTK7 | c.255G>A p.L85= | Silent (SNP) | VAF 14/260 reads (5%) | called by muse, mutect2
- PTPRD | c.2943C>A p.L981= | Silent (SNP) | VAF 60/268 reads (22%) | called by muse, mutect2, varscan2
- RAPGEF2 | c.2316A>C p.A772= | Silent (SNP) | VAF 25/225 reads (11%) | called by muse, mutect2, varscan2
- RUSF1 | c.1406G>A p.*469= | Silent (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
- SCN7A | c.3204C>A p.I1068= | Silent (SNP) | VAF 17/215 reads (8%) | called by muse, mutect2
- SCX | c.549C>T p.L183= | Silent (SNP) | VAF 12/214 reads (6%) | called by muse, mutect2
- SLIT2 | c.3456G>A p.Q1152= | Silent (SNP) | VAF 21/308 reads (7%) | called by muse, mutect2
- SNRNP200 | c.3342C>T p.L1114= | Silent (SNP) | VAF 17/532 reads (3%) | catalogued as COSV60489755; called by muse, mutect2
- SOWAHD | c.639C>T p.D213= | Silent (SNP) | VAF 7/122 reads (6%) | catalogued as rs939081133; called by muse, mutect2
- SULF1 | c.726C>G p.S242= | Silent (SNP) | VAF 22/89 reads (25%) | called by muse, mutect2, varscan2
- TBR1 | c.1386G>T p.P462= | Silent (SNP) | VAF 14/87 reads (16%) | called by muse, mutect2, varscan2
- TCEANC | c.243G>A p.Q81= (on ENST00000380600 / NM_001297563.2; = p.Q111= on NM_152634.4) | Silent (SNP) | VAF 16/298 reads (5%) | called by muse, mutect2
- TCN2 | c.336C>G p.L112= | Silent (SNP) | VAF 18/284 reads (6%) | catalogued as COSV53192759; called by muse, mutect2
- TLL1 | c.654G>A p.R218= | Silent (SNP) | VAF 108/316 reads (34%) | called by muse, mutect2, varscan2
- TNN | c.2790G>T p.P930= | Silent (SNP) | VAF 103/395 reads (26%) | catalogued as rs78387535, COSV53425618; called by muse, mutect2, varscan2
- TRAK2 | c.1527G>A p.R509= | Silent (SNP) | VAF 56/202 reads (28%) | called by muse, mutect2, varscan2
- TTN | c.56181C>A p.P18727= (on ENST00000591111; = p.P11303= on NM_003319.4) | Silent (SNP) | VAF 6/103 reads (6%) | called by muse, mutect2
- UNC80 | c.8787T>C p.S2929= | Silent (SNP) | VAF 7/91 reads (8%) | called by muse, mutect2
- USH2A | c.4776A>T p.V1592= | Silent (SNP) | VAF 36/245 reads (15%) | called by muse, mutect2, varscan2
- WDR17 | c.1683A>G p.V561= | Silent (SNP) | VAF 14/173 reads (8%) | catalogued as rs766574499; called by muse, mutect2
- WDR72 | c.2076T>C p.L692= | Silent (SNP) | VAF 18/78 reads (23%) | called by muse, mutect2, varscan2
- ZBTB46 | c.117C>A p.G39= | Silent (SNP) | VAF 20/195 reads (10%) | called by muse, mutect2, varscan2
- ZFX | c.1929G>C p.S643= | Silent (SNP) | VAF 43/326 reads (13%) | catalogued as COSV58447408; called by muse, mutect2, varscan2
- ZNF33A | c.2361A>G p.Q787= (on ENST00000458705 / NM_006974.3; = p.Q788= on NM_006954.2) | Silent (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2
- ZNF511-PRAP1 | c.639C>A p.G213= | Silent (SNP) | VAF 35/147 reads (24%) | called by muse, mutect2, varscan2
- ZNF792 | c.333T>A p.V111= | Silent (SNP) | VAF 5/33 reads (15%) | called by muse, varscan2
- ACSF2 | c.129-419C>G | Intron (SNP) | VAF 11/154 reads (7%) | called by muse, mutect2
- ADH5P5 | chr5:23979945 C>A | 5'Flank (SNP) | VAF 26/299 reads (9%) | called by muse, mutect2
- AL355390.1 | n.430A>G | RNA (SNP) | VAF 24/202 reads (12%) | called by muse, mutect2, varscan2
- BCORL1 | c.4306-2772C>T | Intron (SNP) | VAF 32/532 reads (6%) | called by muse, mutect2
- BTN3A1 | c.1018+19_1018+20del | Intron (DEL) | VAF 22/125 reads (18%) | called by pindel, varscan2
- C1QTNF8 | c.208+12G>T | Intron (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*42G>A | 3'UTR (SNP) | VAF 74/348 reads (21%) | catalogued as rs200167733; called by muse, mutect2, varscan2
- DMKN | c.1039-1460G>T | Intron (SNP) | VAF 11/146 reads (8%) | called by muse, mutect2
- ECHDC2 | c.122-2252G>T | Intron (SNP) | VAF 22/101 reads (22%) | called by muse, mutect2, varscan2
- ECPAS | c.-32C>T | 5'UTR (SNP) | VAF 8/96 reads (8%) | catalogued as rs1382404494; called by muse, mutect2
- ENDOV | c.838+227C>T | Intron (SNP) | VAF 26/170 reads (15%) | called by muse, mutect2, varscan2
- EPS8L1 | c.430-61G>A | Intron (SNP) | VAF 10/166 reads (6%) | catalogued as COSV52385881; called by muse, mutect2
- FAM189A2 | c.857-46A>C | Intron (SNP) | VAF 83/320 reads (26%) | called by muse, mutect2, varscan2
- FOXP2 | c.-106T>G | 5'UTR (SNP) | VAF 22/338 reads (7%) | called by muse, mutect2
- FSTL1 | c.*1234G>A | 3'UTR (SNP) | VAF 12/288 reads (4%) | catalogued as rs1184386288, COSV99820726; called by muse, mutect2
- GALC | c.*36C>G | 3'UTR (SNP) | VAF 56/248 reads (23%) | called by muse, mutect2, varscan2
- GDPD3 | c.182+73C>G | Intron (SNP) | VAF 42/182 reads (23%) | called by muse, mutect2, varscan2
- GNAS | c.*316G>T | 3'UTR (SNP) | VAF 11/92 reads (12%) | catalogued as rs894054879; called by muse, mutect2, varscan2
- GPKOW | c.-4C>A | 5'UTR (SNP) | VAF 46/328 reads (14%) | called by muse, mutect2, varscan2
- GRB14 | c.325-20550T>C | Intron (SNP) | VAF 15/120 reads (13%) | called by muse, mutect2, varscan2
- GREB1 | c.1346-1337A>G | Intron (SNP) | VAF 52/251 reads (21%) | called by muse, mutect2, varscan2
- GVINP1 | n.1947T>A | RNA (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2
- HLA-DQA1 | c.613+55T>C | Intron (SNP) | VAF 10/242 reads (4%) | called by muse, mutect2
- IL10RA | c.*384G>C | 3'UTR (SNP) | VAF 12/220 reads (5%) | called by muse, mutect2
- KCNMA1 | c.1928+2376C>A | Intron (SNP) | VAF 54/209 reads (26%) | catalogued as rs1303634345; called by muse, mutect2, varscan2
- KCTD17 | c.734-11del | Intron (DEL) | VAF 43/255 reads (17%) | called by mutect2, pindel, varscan2
- LARS2 | c.-2G>A | 5'UTR (SNP) | VAF 34/124 reads (27%) | called by muse, mutect2, varscan2
- LINC00602 | n.1137G>T | RNA (SNP) | VAF 16/102 reads (16%) | catalogued as rs898650335; called by muse, mutect2, varscan2
- LPAL2 | n.163A>G | RNA (SNP) | VAF 39/276 reads (14%) | catalogued as rs772816836; called by muse, mutect2, varscan2
- MIR9-1 | chr1:156420303 G>T | 3'Flank (SNP) | VAF 90/468 reads (19%) | called by muse, mutect2, varscan2
- MPHOSPH10 | c.1240+36C>T | Intron (SNP) | VAF 62/334 reads (19%) | called by muse, mutect2, varscan2
- MTNR1A | c.*32G>T | 3'UTR (SNP) | VAF 21/181 reads (12%) | catalogued as COSV100208360; called by muse, mutect2, varscan2
- MXRA8 | c.1106-24C>T | Intron (SNP) | VAF 12/224 reads (5%) | called by muse, mutect2
- NDUFS7 | chr19:1383715 G>A | 5'Flank (SNP) | VAF 24/382 reads (6%) | called by muse, mutect2
- PGM1 | c.247-5753A>T | Intron (SNP) | VAF 12/195 reads (6%) | called by muse, mutect2
- PHGDH | c.643+111T>A | Intron (SNP) | VAF 16/103 reads (16%) | catalogued as rs1335922445; called by muse, mutect2, varscan2
- PPIL2 | c.-17G>T | 5'UTR (SNP) | VAF 17/119 reads (14%) | called by muse, mutect2, varscan2
- PPP1R9A | c.2757+5194G>T | Intron (SNP) | VAF 52/203 reads (26%) | called by muse, mutect2, varscan2
- PRDM5 | c.865+126C>A | Intron (SNP) | VAF 22/170 reads (13%) | catalogued as rs753936958; called by muse, mutect2, varscan2
- PTPA | c.999+70A>T | Intron (SNP) | VAF 25/105 reads (24%) | called by muse, mutect2, varscan2
- RACK1 | c.109+429C>T | Intron (SNP) | VAF 24/313 reads (8%) | called by muse, mutect2
- REPS1 | c.1136-4227C>T | Intron (SNP) | VAF 10/113 reads (9%) | called by muse, mutect2
- RIIAD1 | c.-960C>T | 5'UTR (SNP) | VAF 22/284 reads (8%) | called by muse, mutect2
- SDHAP3 | n.220A>T | RNA (SNP) | VAF 27/720 reads (4%) | called by muse, mutect2
- SKP1P2 | n.82A>T | RNA (SNP) | VAF 18/285 reads (6%) | called by muse, mutect2
- SRP19 | c.*1136G>A | 3'UTR (SNP) | VAF 28/234 reads (12%) | catalogued as rs1372724479; called by muse, mutect2, varscan2
- SSPOP | n.4928C>A | RNA (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2
- TGFBR3 | c.*1142C>A | 3'UTR (SNP) | VAF 42/401 reads (10%) | called by muse, mutect2, varscan2
- TMEM183B | n.370G>A | RNA (SNP) | VAF 18/461 reads (4%) | called by muse, mutect2
- TTN | c.10360+2706G>T | Intron (SNP) | VAF 46/190 reads (24%) | catalogued as rs144909083; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- XIRP2 | c.*1212C>G | 3'UTR (SNP) | VAF 7/113 reads (6%) | called by muse, mutect2
- ZNF311 | c.9+21G>C | Intron (SNP) | VAF 20/234 reads (9%) | catalogued as rs562494577; called by muse, mutect2
- ZNRF1 | c.520+2017G>C | Intron (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
